Somatic mutation profile of tumor specimen TCGA-AR-A5QP-01A (aliquot TCGA-AR-A5QP-01A-11D-A28B-09) from TCGA case TCGA-AR-A5QP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.2 years (19,805 days).
Specimen TCGA-AR-A5QP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de54ba8e-63be-42de-9488-036f4c134d32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A5QP-10A (Blood Derived Normal), aliquot TCGA-AR-A5QP-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6a2f4fa-e32d-42de-87d1-0bea46f789c6

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Frame Shift Del 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CA5A | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs142182110; called by muse, mutect2, varscan2
- CMBL | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs199662372, COSV56985250; called by muse, mutect2, varscan2
- ERCC3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406400169, COSV53429855; called by muse, mutect2, varscan2
- FUNDC2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs782780466, COSV65671652; called by muse, mutect2, varscan2
- GDPD4 | c.22del p.E8Kfs*15 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV60022884; called by mutect2, varscan2
- ITGA10 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV65196843, COSV65199161; called by muse, mutect2, varscan2
- MYPN | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100590303; called by muse, mutect2
- OR12D2 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV65830230; called by muse, mutect2, varscan2
- P3H1 | c.1734G>T p.E578D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV52537216; called by muse, mutect2, varscan2
- PIP5KL1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV55945411; called by muse, mutect2
- SEZ6L2 | c.2293G>A p.A765T (on ENST00000308713 / NM_001114099.3; = p.A695T on NM_012410.4) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs375292147, COSV100435739, COSV58097371; called by muse, mutect2, varscan2
- SLC22A9 | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs757007403, COSV54170266; called by muse, mutect2, varscan2
- SMIM14 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV55905895; called by muse, mutect2, varscan2
- TTN | c.23503G>A p.V7835I (on ENST00000591111; = p.V6908I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | PolyPhen benign (0.012); catalogued as rs397517507, COSV60334381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VDAC3 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs551923370, COSV50082166; called by muse, mutect2, varscan2
- WWC1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1368568779, COSV54658320; called by muse, mutect2, varscan2
- ZNF582 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100018825, COSV56733042; called by muse, mutect2
- AAMP | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2
- PLK2 | c.1161_1162del p.R387Sfs*3 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by pindel, varscan2
- FERMT2 | c.804G>A p.E268= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100449009; called by muse, mutect2
- SLITRK1 | c.193C>T p.L65= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV65675062, COSV65677509; called by muse, mutect2, varscan2
